Somatic mutation profile of tumor specimen TCGA-GN-A26D-06A (aliquot TCGA-GN-A26D-06A-11D-A19A-08) from TCGA case TCGA-GN-A26D, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.6 years (27,251 days).
Specimen TCGA-GN-A26D-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dfc6a5f-9a60-4e2e-8e9c-72ad9cc5fe4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A26D-10A (Blood Derived Normal), aliquot TCGA-GN-A26D-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f74f4ec6-abcd-4d39-8fc0-34628f410a73

The open-access MAF lists 44 somatic variants for this specimen: 39 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 31, Nonsense Mutation 5, Silent 5, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD4 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58850713; called by muse, mutect2, varscan2
- ADAMTS10 | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV54351967; called by muse, mutect2, varscan2
- CASS4 | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64385405; called by mutect2, varscan2
- CD99 | c.263-1G>T p.X88_splice | Splice Site (SNP) | VAF 34/192 reads (18%) | catalogued as COSV66989190; called by mutect2, varscan2
- CRTAC1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764021235, COSV53997045; called by mutect2, varscan2
- DSCAM | c.4642A>T p.M1548L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV68020892, COSV68024087; called by muse, mutect2, varscan2
- ELAVL4 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63914241; called by muse, mutect2, varscan2
- GALNT14 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61102482; called by mutect2, varscan2
- GLRA4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs760985980, COSV60327251, COSV60328111; called by muse, mutect2, varscan2
- HCAR2 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV61024276; called by muse, varscan2
- HDAC5 | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56817177, COSV56820248; called by muse, mutect2, varscan2
- HEATR4 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV58569849, COSV58570183; called by mutect2, varscan2
- ITGAM | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54933669; called by muse, varscan2
- JUP | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.138); catalogued as COSV60277050; called by muse, mutect2, varscan2
- KCNMA1 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV54227714; called by muse, mutect2, varscan2
- KMT2A | c.9625A>G p.T3209A | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.138); catalogued as COSV63281975; called by muse, mutect2, varscan2
- KRT6C | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV52876390; called by mutect2, varscan2
- MAP3K4 | c.3178C>T p.Q1060* | Nonsense Mutation (SNP) | VAF 77/130 reads (59%) | catalogued as COSV62330144; called by muse, mutect2, varscan2
- MAP7D2 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65525621; called by muse, mutect2, varscan2
- MUC4 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV62129349; called by muse, mutect2, varscan2
- NCOR1 | c.4072G>C p.D1358H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51961002; called by muse, mutect2, varscan2
- NCOR1 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51961033; called by muse, mutect2, varscan2
- NNMT | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 60/94 reads (64%) | catalogued as COSV55472914, COSV55472981; called by mutect2, varscan2
- ODF1 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs1049280656, COSV53431558, COSV53432595; called by mutect2, varscan2
- PDC | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV60853907; called by mutect2, varscan2
- PES1 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58827911; called by muse, mutect2, varscan2
- PLXNC1 | c.2329A>T p.R777* | Nonsense Mutation (SNP) | VAF 15/18 reads (83%) | catalogued as COSV51569376; called by muse, mutect2, varscan2
- PPTC7 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62825733, COSV62827650; called by muse, mutect2, varscan2
- PRG4 | c.1838C>G p.P613R | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV63354937; called by muse, mutect2, varscan2
- RASSF8 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452617; called by mutect2, varscan2
- SHMT2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61073162; called by muse, mutect2
- SLC17A7 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145455204, COSV55546441; called by mutect2, varscan2
- TAS2R38 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as rs1259634484, COSV71884973; called by muse, mutect2, varscan2
- TTI1 | c.2411C>A p.T804N | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV65060444, COSV65063792; called by muse, mutect2, varscan2
- TTN | c.5981C>T p.S1994L (on ENST00000591111; = p.S1948L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | PolyPhen possibly damaging (0.683); catalogued as rs758483877, COSV59887888; called by muse, mutect2, varscan2
- ZFR2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53596360; called by muse, mutect2
- CD151 | c.-1_9del | Translation Start Site (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SLC9A6 | c.1761T>A p.D587E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- SPRED1 | c.1149dup p.E384Rfs*6 | Frame Shift Ins (INS) | VAF 11/16 reads (69%) | called by mutect2, pindel, varscan2
- CD70 | c.210C>T p.D70= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV55565576; called by muse, mutect2, varscan2
- MET | c.420C>G p.T140= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV59256868; called by muse, mutect2, varscan2
- PHF24 | c.952C>A p.R318= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV54273006; called by muse, mutect2, varscan2
- PSPC1 | c.1326C>T p.A442= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV58886520; called by mutect2, varscan2
- SON | c.1809T>C p.A603= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV51650570; called by muse, mutect2, varscan2
